Surgical pathology report (de-identified scan), TCGA case TCGA-38-4627, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site UNC, specimen TCGA-38-4627-01A (Primary Tumor).

[page 1 of 2]
Diagnosis:

A: Lung, right upper lobe, lobectomy.

- Adenocarcinoma, moderately differentiated, 2.7 cm diameter, without angiolymphatic invasion, without pleural involvement, bronchial margin not involved.
- Lymph nodes, peribronchial - Metastatic adenocarcinoma (1/4), without extracapsular extension.

B: Lymph node, R4, removal.

- No metastatic carcinoma identified (0/1).

C: Lymph node, station 11, removal.

- No metastatic carcinoma identified (0/1).

Comment:

None.

Clinical History:

The patient is with right NSCLC, in for right thoracotomy.

Gross Description:

Received are three appropriately labeled containers.

Container A is additionally labeled "RUL."

Specimen fixation: formalin

Type of specimen/parts of lung received: right upper lobectomy

Size of specimen: 13.8 x 9.2 x 3.0 cm

Weight of specimen: 215 grams

Other attached structures: n/a

Tumor location: central

Tumor size and description: The tumor mass is a 2.7 x 2.0 x 1.6 cm firm, tan mass with stellate borders and focal areas of gray discoloration scattered across the cut surface.

Relationship of tumor to bronchus: does not grossly involve

Distance of tumor to bronchial margin: approximately 2.9 cm

Relationship/distance of tumor to pleura: the tumor nodule is grossly abutting the overlying blue inked pleura

Distance of tumor to other surgical margins: There is a complex staple line running across the specimen, and the tumor nodule is at least 0.6 cm from the staple line.

Presence/absence of satellite tumor nodules: absent

Involvement of attached structures by tumor: n/a

Description of nontumorous lung: Dark, red/tan, soft, spongy and aerated lung parenchyma with no other lesions or abnormalities identified.

Comment: The following is submitted to Tissue Procurement: the bronchial margin was removed and the next cross section of bronchus was given to Tissue Procurement, representative tumor and representative normal lung were also given to Tissue procurement.

Block Summary:

- A1 - bronchial margin and vascular margins
- A2 - one peribronchial lymph node candidate, bisected
- A3 - one peribronchial lymph node candidate
- A4,A5 - tumor overlying pleura
- A6 - tumor and adjacent parenchyma
- 7 - uninvolved lung

Container B is additionally labeled "R4." It holds a 0.8 x 0.5 x 0.3 cm fragment of dark purple/gray tissue which is bisected and submitted in block B1, NTR.

Container C is additionally labeled "station 11." It holds a 0.6 x 0.5 x 0.3 cm fragment of dark gray/red soft

[page 2 of 2]
tissue, which is submitted in block C1, [REDACTED]

Light Microscopy:

Light microscopic examination is performed by [REDACTED]

(Specimen A)

Tumor histologic type (WHO classification): adenocarcinoma

Tumor histologic grade (WHO classification): moderately differentiated

Tumor size (greatest dimension): 2.7 cm diameter

Histologic assessment of surgical margins: negative

Pleural involvement: not identified

In situ carcinoma: not identified

Invasion:

angiolymphatic - not identified

perineural - not identified

Lymph nodes (by node group): peribronchial 1/4, R4 0/1, station 11 0/1

Extracapsular extension of tumor in lymph nodes: not identified

Findings in nontumorous lung: anthracotic pigment

■

Source: NCI Genomic Data Commons file 0cccbb8f-94e4-4e9b-b736-257baa12f428 (TCGA-38-4627.255A7CA7-4AA4-4014-884C-33C331AF765D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).